CCDI case PBBVRV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/40e12d8a-df38-41c4-80b7-908e4d70aabf

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.6 years (4,600 days).

Biospecimens (3 samples)
- Sample 0DII3B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
